Somatic mutation profile of tumor specimen TCGA-13-0807-01B (aliquot TCGA-13-0807-01B-02W-0421-09) from TCGA case TCGA-13-0807, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.5 years (19,890 days).
Specimen TCGA-13-0807-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1502f45e-079a-4c06-b097-d6962725ce65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0807-10A (Blood Derived Normal), aliquot TCGA-13-0807-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1da12ec-8d97-4b37-9558-bcb9d6863748

The open-access MAF lists 172 somatic variants for this specimen: 128 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 40, Nonsense Mutation 10, Splice Region 2, 5'Flank 2, Splice Site 2, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHEX | c.933+1G>T p.X311_splice | Splice Site (SNP) | VAF 69/167 reads (41%) | catalogued as rs1556025314, CS971857, COSV65073787, COSV65078280; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1131691029, COSV52731052, COSV52823875, COSV52978993; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACD | c.597C>T p.P199= (on ENST00000620338; = p.P110= on NM_022914.3) | Splice Region (SNP) | VAF 16/65 reads (25%) | catalogued as rs1322815478, COSV54667662; called by muse, varscan2
- ACSS1 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100053951; called by muse, mutect2, varscan2
- ADGRB3 | c.2414T>C p.I805T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV65383243; called by muse, mutect2, varscan2
- ADGRE3 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs773754562, COSV53728406; called by muse, varscan2
- ADGRV1 | c.7102A>G p.S2368G | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV67978684, COSV67997240; called by muse, mutect2, varscan2
- AKAP4 | c.872A>C p.E291A | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV62073712; called by muse, mutect2, varscan2
- ANKZF1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.71); catalogued as COSV99850805; called by muse, mutect2
- ATF7 | c.325C>G p.L109V (on ENST00000548446 / NM_001366555.2; = p.L98V on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.51); PolyPhen benign (0.146); catalogued as COSV60642229; called by muse, mutect2, varscan2
- BEX2 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV101012850; called by muse, mutect2
- BRINP1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV56296019, COSV99776474; called by muse, mutect2
- BRWD3 | c.4499C>G p.S1500* | Nonsense Mutation (SNP) | VAF 35/142 reads (25%) | catalogued as COSV64744003; called by muse, mutect2, varscan2
- CARS1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53462036, COSV99543299; called by muse, mutect2, varscan2
- CCDC110 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as rs767520981, COSV100294110; called by muse, varscan2
- CCDC3 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66558513; called by muse, mutect2, varscan2
- CDH1 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1215319435, COSV99932466; ClinVar: uncertain significance; called by muse, mutect2
- CDON | c.1965G>T p.M655I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54995202; called by muse, mutect2, varscan2
- CIB3 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV54165433; called by muse, mutect2, varscan2
- CLDN10 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV65296459; called by muse, mutect2, varscan2
- COG8 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99650866; called by muse, mutect2, varscan2
- COL7A1 | c.8590C>T p.Q2864* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV99866397; called by muse, varscan2
- CXXC5 | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV56796025; called by muse, mutect2
- CYP2R1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as rs782803589, COSV58126681; called by muse, mutect2, varscan2
- DHRS7 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 110/459 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53665332; called by muse, mutect2, varscan2
- DIMT1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV99551180; called by muse, mutect2
- DISP2 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs758069989, COSV99140335; called by muse, varscan2
- DNAH3 | c.12067G>C p.E4023Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54503721, COSV54504721; called by muse, mutect2, varscan2
- DNER | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as COSV100519761, COSV59166022; called by muse, mutect2, varscan2
- DOCK2 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs752262388, COSV56942620, COSV56968077; called by muse, mutect2, varscan2
- DYSF | c.2570G>T p.W857L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50268706; called by muse, mutect2
- EFEMP2 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100337355; called by muse, mutect2, varscan2
- EIF3E | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1482317769, COSV55201495, COSV99622697; called by muse, mutect2, varscan2
- ELAPOR1 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100884464; called by muse, mutect2
- F13A1 | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 21/690 reads (3%) | catalogued as COSV99343660; called by muse, mutect2
- FAM171A1 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968426; called by muse, mutect2
- FAM47B | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV61452550; called by muse, mutect2, varscan2
- FAM71F1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171099; called by muse, mutect2
- FLT1 | c.3646G>T p.A1216S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV99164917; called by muse, mutect2
- GLDC | c.1492G>C p.A498P | Missense Mutation (SNP) | VAF 147/320 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.584); catalogued as COSV58676581; called by muse, mutect2, varscan2
- GPS2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.991); catalogued as rs774633910, COSV59747130; called by muse, mutect2, varscan2
- H2BC15 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV100357055; called by muse, mutect2, varscan2
- H2BC9 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs370727098; called by muse, mutect2
- HIVEP1 | c.6823G>A p.G2275R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101045535; called by muse, mutect2
- IFNA1 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 110/897 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV52806429; called by muse, varscan2
- IGSF10 | c.7579C>T p.P2527S | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV99191753; called by muse, mutect2
- INTS6 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV100247199; called by muse, mutect2, varscan2
- JAK3 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV71685373; called by muse, varscan2
- KANK1 | c.3138G>A p.M1046I | Missense Mutation (SNP) | VAF 40/1352 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100620019; called by muse, mutect2
- KIAA1755 | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs760553122, COSV99642458; called by muse, mutect2, varscan2
- KLK3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386066; called by muse, mutect2, varscan2
- LPO | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51856830; called by muse, mutect2, varscan2
- LRCH2 | c.2229A>T p.K743N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57746175; called by muse, mutect2, varscan2
- LRRC37A3 | c.4814G>A p.C1605Y | Missense Mutation (SNP) | VAF 294/362 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100141380; called by muse, mutect2, varscan2
- MANBA | c.2530G>T p.G844W (on ENST00000642252; = p.G798W on NM_005908.4) | Missense Mutation (SNP) | VAF 50/818 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899037; called by muse, mutect2
- MAST2 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs756675811, COSV63616167; called by muse, mutect2, varscan2
- MDN1 | c.15257C>T p.S5086F | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101021664; called by muse, varscan2
- MFHAS1 | c.2541G>T p.W847C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99359815; called by muse, mutect2
- MGLL | c.480G>A p.K160= (on ENST00000398104 / NM_001003794.2; = p.K170= on NM_007283.6) | Splice Region (SNP) | VAF 10/105 reads (10%) | catalogued as COSV99412214; called by muse, mutect2
- MNDA | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63739923, COSV63742122; called by muse, mutect2, varscan2
- MTG2 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762450102, COSV100895191; called by muse, varscan2
- MTG2 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63693400; called by muse, varscan2
- MYH1 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56843803; called by muse, varscan2
- MYOM1 | c.2683G>T p.E895* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV99867854; called by muse, mutect2, varscan2
- N4BP3 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99200777; called by muse, mutect2, varscan2
- NBEA | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59760937; called by muse, mutect2, varscan2
- NKRF | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100441828; called by muse, mutect2, varscan2
- NUP98 | c.4489A>G p.K1497E (on ENST00000359171 / NM_001365126.1; = p.K1480E on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100263164; called by muse, mutect2, varscan2
- OR10G7 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100390031, COSV57865637; called by muse, mutect2, varscan2
- OR5D14 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59455310, COSV59455395; called by muse, mutect2, varscan2
- OR8B8 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 300/628 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV60143737; called by muse, varscan2
- PAF1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 34/982 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55395435; called by muse, mutect2
- PAMR1 | c.1631C>T p.S544F (on ENST00000619888 / NM_001001991.3; = p.S561F on NM_015430.4) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866793106, COSV53513685, COSV53513930; called by muse, mutect2
- PDE4A | c.2467G>A p.A823T (on ENST00000380702 / NM_001111307.2; = p.A584T on NM_006202.3) | Missense Mutation (SNP) | VAF 73/299 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.398); catalogued as COSV99534896; called by muse, mutect2, varscan2
- PLEKHG6 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99164786; called by muse, mutect2
- PPP1R7 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.182); catalogued as rs1028285376, COSV99298112; called by muse, mutect2
- PTCH1 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs766898310, COSV59463224, COSV59499687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN18 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375251896; called by muse, mutect2, varscan2
- RANBP2 | c.8932G>A p.V2978I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs950108961; called by muse, mutect2
- RGS7 | c.434T>A p.L145H | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58531094; called by muse, mutect2, varscan2
- RIMS2 | c.2549A>C p.Y850S (on ENST00000666250 / NM_001348490.2; = p.Y658S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51653911; called by muse, mutect2, varscan2
- RNF19A | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100347992; called by muse, mutect2
- RPS6KB1 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV99847691; called by muse, mutect2
- SALL3 | c.3760G>T p.G1254C | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV73305765; called by muse, mutect2, varscan2
- SEMA4B | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.06); catalogued as COSV100153371; called by muse, mutect2, varscan2
- SEMA6D | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 14/277 reads (5%) | catalogued as COSV100317388; called by muse, mutect2
- SEMG1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV99725311; called by muse, mutect2
- SGSM3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs780477111, COSV50651215; called by muse, mutect2, varscan2
- SHOC1 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV59497698, COSV59500207; called by muse, mutect2, varscan2
- SLC4A10 | c.1711C>T p.P571S (on ENST00000446997 / NM_001354461.2; = p.P541S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99765197; called by muse, mutect2
- SOX15 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100002170; called by muse, mutect2, varscan2
- SPDYC | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 42/322 reads (13%) | catalogued as COSV101017265; called by muse, mutect2
- TAC3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1383778839, COSV100269913; called by muse, mutect2, varscan2
- TBX6 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99661746; called by muse, varscan2
- TBXT | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV51616882; called by muse, mutect2
- TCP11 | c.994G>T p.V332F (on ENST00000512012; = p.V270F on NM_018679.5) | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as rs765786893, COSV55131752, COSV55133326; called by muse, mutect2, varscan2
- TLN1 | c.6598G>A p.D2200N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59204393; called by muse, mutect2
- TMOD1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99404075; called by muse, mutect2, varscan2
- TNRC6A | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1440247251, COSV100170365; called by muse, mutect2
- TSPAN12 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99763307; called by muse, mutect2
- TTN | c.98806C>G p.Q32936E (on ENST00000591111; = p.Q25512E on NM_003319.4) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | PolyPhen possibly damaging (0.717); catalogued as COSV59893179, COSV60293395; called by muse, mutect2, varscan2
- UBA2 | c.1246-1G>T p.X416_splice | Splice Site (SNP) | VAF 40/171 reads (23%) | catalogued as COSV55827325, COSV55829013; called by muse, mutect2, varscan2
- UBASH3A | c.1914C>G p.N638K | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV52310564; called by muse, mutect2, varscan2
- UGT1A7 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529928629, COSV100693077; called by muse, mutect2
- URB2 | c.3529G>T p.A1177S | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99271660; called by muse, mutect2
- VN1R4 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV60804643, COSV60805321; called by muse, varscan2
- WDR6 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186767522, COSV100556661; called by muse, mutect2
- XYLB | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52911538; called by muse, mutect2, varscan2
- ZNF214 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 34/1132 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99547574; called by muse, mutect2
- ZNF529 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as rs1318584511; called by muse, mutect2
- ARPP21 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- COX4I1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- CRAT | c.1406_1441del p.R469_A481delinsP | In Frame Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- DIS3L2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMD | c.10079G>A p.C3360Y | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IPO7 | c.1277C>G p.P426R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- MID1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MRPL58 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- MSH6 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 44/438 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- MYO1G | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- NUAK2 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OXCT2 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIM2 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBM6 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- USP24 | c.4400C>T p.S1467L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WFDC8 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 68/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF618 | c.1376G>A p.S459N (on ENST00000374126 / NM_001318042.2; = p.S366N on NM_133374.2) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- ZZEF1 | c.5015C>T p.P1672L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ABCB6 | c.1746C>T p.P582= | Silent (SNP) | VAF 38/211 reads (18%) | called by muse, mutect2, varscan2
- ANKRD17 | c.7098C>T p.N2366= | Silent (SNP) | VAF 115/420 reads (27%) | catalogued as COSV58215547; called by muse, mutect2, varscan2
- ATP6V0A4 | c.927G>A p.L309= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV59480244; called by muse, mutect2
- CA14 | c.759G>A p.E253= | Silent (SNP) | VAF 65/1082 reads (6%) | catalogued as rs149155658; called by muse, mutect2
- CEMIP2 | c.2844C>T p.S948= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as COSV100987145; called by muse, mutect2
- CES4A | c.106C>T p.L36= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- COMTD1 | c.780C>T p.F260= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs940661307, COSV100041013, COSV100041061; called by muse, varscan2
- DNAJC22 | c.15C>T p.L5= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV101222591; called by muse, mutect2
- EIF5B | c.957G>A p.K319= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- GSE1 | c.1377C>T p.P459= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99497050; called by muse, mutect2, varscan2
- HPF1 | c.621C>T p.T207= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as COSV66421515, COSV66421589; called by muse, mutect2, varscan2
- IGKV2D-29 | c.306G>C p.R102= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as COSV72391463; called by muse, mutect2, varscan2
- IGSF10 | c.7578C>T p.Y2526= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as rs1282512374, COSV99191769; called by muse, mutect2
- INTS6 | c.2235G>A p.L745= | Silent (SNP) | VAF 102/201 reads (51%) | catalogued as COSV100247201; called by muse, mutect2, varscan2
- ITPR2 | c.2668C>T p.L890= | Silent (SNP) | VAF 6/180 reads (3%) | catalogued as rs1043435317; called by muse, mutect2
- KCNK16 | c.858C>G p.G286= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV64677214; called by muse, mutect2, varscan2
- LILRB5 | c.1719C>T p.S573= (on ENST00000449561 / NM_001081442.3; = p.S572= on NM_006840.5) | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as COSV100300678; called by muse, mutect2
- LMX1A | c.145C>A p.R49= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1359145261, COSV54217243, COSV99672897; called by mutect2, varscan2
- MAST2 | c.3534G>A p.L1178= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100788621; called by muse, mutect2, varscan2
- MCM3AP | c.2574G>A p.L858= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV99387332; called by muse, mutect2
- NBEAL1 | c.4956C>T p.F1652= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV71375432; called by muse, mutect2
- NCOA6 | c.1815C>T p.N605= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV100750250; called by muse, mutect2, varscan2
- NLRC4 | c.2038C>T p.L680= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as COSV100707478; called by muse, mutect2
- OR2AG1 | c.855G>A p.L285= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as COSV100264930, COSV100264937; called by muse, mutect2, varscan2
- OR6V1 | c.228G>A p.V76= | Silent (SNP) | VAF 46/788 reads (6%) | catalogued as COSV69237369; called by muse, mutect2
- PCDHB11 | c.834C>T p.C278= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as rs1396804760, COSV53382006, COSV99504795; called by muse, mutect2
- PDE12 | c.570C>T p.P190= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100239932; called by muse, varscan2
- PNMA8A | c.1068G>A p.K356= | Silent (SNP) | VAF 220/482 reads (46%) | catalogued as COSV58135652, COSV58138257; called by muse, mutect2, varscan2
- PRAMEF1 | c.396G>A p.R132= | Silent (SNP) | VAF 44/936 reads (5%) | catalogued as rs753961214; called by muse, mutect2
- PROM2 | c.162T>G p.V54= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV58296691; called by muse, mutect2, varscan2
- RBM12B | c.2283G>A p.E761= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV101234549; called by muse, mutect2, varscan2
- REXO2 | c.321C>T p.T107= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV56277872; called by muse, mutect2
- SPAG9 | c.3795C>T p.P1265= (on ENST00000262013 / NM_001130528.3; = p.P1251= on NM_003971.6) | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100005710, COSV100005963; called by muse, mutect2
- TAS2R41 | c.168C>T p.F56= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV101281510; called by muse, varscan2
- TULP2 | c.1347C>T p.T449= | Silent (SNP) | VAF 35/291 reads (12%) | catalogued as COSV99668023; called by muse, mutect2, varscan2
- UBXN10 | c.39G>A p.E13= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as rs534420264, COSV66771833; called by muse, mutect2, varscan2
- VCAN | c.435G>A p.L145= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99426828; called by muse, mutect2, varscan2
- VDAC1 | c.252G>A p.E84= | Silent (SNP) | VAF 140/766 reads (18%) | catalogued as COSV99527300; called by muse, mutect2, varscan2
- VN1R4 | c.321C>A p.I107= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV60804638, COSV60804854; called by muse, mutect2, varscan2
- ZNF774 | c.369C>A p.T123= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV100586437; called by muse, mutect2
- AL353804.7 | chrX:73845935 ins A | 5'Flank (INS) | VAF 13/98 reads (13%) | called by mutect2, pindel, varscan2
- FOLH1B | n.1268G>A | RNA (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2597G>A | Intron (SNP) | VAF 12/51 reads (24%) | catalogued as COSV57627259; called by muse, mutect2, varscan2
- STMP1 | chr7:135660261 A>G | 5'Flank (SNP) | VAF 144/267 reads (54%) | catalogued as rs776334105; called by muse, varscan2
